Somatic mutation profile of tumor specimen TCGA-UY-A9PA-01A (aliquot TCGA-UY-A9PA-01A-11D-A38G-08) from TCGA case TCGA-UY-A9PA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 48.0 years (17,520 days).
Specimen TCGA-UY-A9PA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6459901-771b-472b-b5bf-e13c6504a54b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A9PA-10A (Blood Derived Normal), aliquot TCGA-UY-A9PA-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b42bafc-53db-4777-9d4e-ffc3842b5ef0

The open-access MAF lists 169 somatic variants for this specimen: 124 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 41, Nonsense Mutation 6, Splice Site 4, Frame Shift Del 4, RNA 2, Intron 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3148C>G p.P1050A | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.402); catalogued as COSV57051735; called by muse, mutect2
- ADAM2 | c.371G>C p.S124T | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.699); catalogued as COSV55860505; called by muse, mutect2
- ADCY2 | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV57866409; called by muse, mutect2
- AEBP1 | c.2999G>A p.R1000Q | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV56256613; called by muse, mutect2
- AHNAK2 | c.5469C>G p.F1823L | Missense Mutation (SNP) | VAF 68/628 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs375980238, COSV60911860, COSV60931320; called by muse, varscan2
- ALG11 | c.682T>C p.F228L | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV73000621; called by muse, mutect2
- ALPK3 | c.1945A>G p.K649E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51931829; called by muse, mutect2, varscan2
- ANAPC7 | c.1727A>G p.E576G | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV101482867; called by muse, mutect2
- APLNR | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV57241944; called by muse, mutect2
- ARHGAP32 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 11/168 reads (7%) | catalogued as COSV100088159; called by muse, mutect2
- ATRX | c.6524T>C p.I2175T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64874170; called by muse, mutect2, varscan2
- BACH2 | c.731A>T p.N244I | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV57588753; called by muse, mutect2
- CACNA1A | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64189098; called by muse, mutect2
- CBLN2 | c.381C>A p.H127Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as rs1348973100, COSV54050129; called by muse, mutect2, varscan2
- CDCA7 | c.785A>T p.Y262F (on ENST00000347703 / NM_145810.3; = p.Y341F on NM_031942.5) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60720122; called by muse, mutect2
- CDH16 | c.993C>A p.D331E | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55335821; called by muse, mutect2
- CERCAM | c.1349A>C p.Q450P | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV65710705; called by muse, mutect2
- CHCHD7 | c.16C>A p.Q6K (on ENST00000355315 / NM_001011671.3; = p.Q18K on NM_024300.4) | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57610275; called by muse, mutect2
- CHFR | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV57173142; called by muse, mutect2, varscan2
- CLCN3 | c.1948C>T p.H650Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs1433300940, COSV61626744; called by muse, mutect2, varscan2
- CLIP4 | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); catalogued as rs770201491, COSV60748532; called by muse, mutect2, varscan2
- CLP1 | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1253045023, COSV57054189; called by muse, mutect2
- COL22A1 | c.2201C>A p.P734H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57330828; called by muse, mutect2
- COL5A1 | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV65667523; called by muse, mutect2, varscan2
- COL5A1 | c.4708G>A p.G1570R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65667527; called by muse, mutect2, varscan2
- CPSF7 | c.40G>T p.E14* (on ENST00000394888 / NM_001136040.4; = p.E57* on NM_024811.4) | Nonsense Mutation (SNP) | VAF 19/220 reads (9%) | catalogued as COSV100073961, COSV100073992, COSV57099852; called by muse, mutect2
- CSNK1D | c.62G>C p.G21A | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100012509; called by muse, mutect2
- CTTNBP2 | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50393787; called by muse, mutect2
- CUX2 | c.3723C>A p.S1241R | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs775186252, COSV55628402; called by muse, mutect2, varscan2
- CYP2E1 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53312885; called by muse, mutect2, varscan2
- CYP7B1 | c.260-2A>T p.X87_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as rs1239597675, COSV100042176; called by muse, mutect2
- DACH1 | c.1026G>A p.M342I | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV57494844; called by muse, mutect2
- DMXL1 | c.3413A>G p.H1138R | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV60708385; called by muse, mutect2, varscan2
- DNAH5 | c.2956C>G p.H986D | Missense Mutation (SNP) | VAF 5/141 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99451043; called by muse, mutect2
- EHBP1 | c.996A>G p.I332M | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV50417985; called by muse, mutect2
- EIF4E2 | c.541T>C p.S181P | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51471543; called by muse, mutect2, varscan2
- ENGASE | c.1304T>G p.L435W | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV56134967; called by muse, mutect2
- ERBIN | c.1921_1922del p.D641Ffs*5 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs1168815964; called by mutect2, varscan2
- FAM83H | c.2554C>G p.L852V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs782033920, COSV62027858; called by muse, mutect2, varscan2
- FANCA | c.3072G>C p.M1024I | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99981620; called by muse, mutect2
- FCHO1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as rs1350972636, COSV53181734; called by muse, mutect2
- FER1L6 | c.3616T>G p.S1206A | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.874); catalogued as COSV67549113; called by muse, mutect2
- FEZ1 | c.498+2T>C p.X166_splice | Splice Site (SNP) | VAF 6/108 reads (6%) | catalogued as COSV54027524; called by muse, mutect2
- FGD3 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100490840, COSV61596513; called by muse, mutect2
- FOXJ2 | c.1093A>T p.M365L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV50817904; called by muse, mutect2
- FRY | c.5267C>G p.S1756* | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | catalogued as COSV100969418; called by muse, mutect2
- GCN1 | c.7231G>T p.V2411L | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV56105805; called by muse, mutect2
- GMPPB | c.911A>C p.E304A | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV57538063; called by muse, mutect2
- GP9 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs137994346; called by muse, mutect2, varscan2
- GRIA1 | c.2474T>C p.L825S | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV53596995; called by muse, mutect2
- GRIA2 | c.1754G>C p.S585T | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV52386665; called by muse, mutect2
- HEATR1 | c.2756-1G>C p.X919_splice | Splice Site (SNP) | VAF 6/83 reads (7%) | catalogued as COSV63980352; called by muse, mutect2
- HRNR | c.1345T>C p.S449P | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV64256328; called by muse, mutect2
- IRAK1BP1 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV64048077; called by muse, mutect2, varscan2
- KIF14 | c.3886T>G p.L1296V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV66260978; called by muse, mutect2, varscan2
- KLHDC2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV53586917; called by muse, mutect2
- KRTAP10-5 | c.596G>T p.C199F | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV59957007; called by muse, mutect2
- LGR6 | c.403T>G p.W135G (on ENST00000367278 / NM_001017403.1; = p.W83G on NM_021636.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV55154442; called by muse, mutect2
- LIG4 | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV63596740; called by muse, mutect2
- LONP2 | c.861T>G p.H287Q | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV53521514; called by muse, mutect2
- LPL | c.130A>T p.R44W | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60930721; called by muse, mutect2
- LRRC37B | c.1109C>A p.P370Q | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58951631; called by muse, mutect2
- MARCHF1 | c.283A>G p.T95A (on ENST00000274056; = p.T78A on NM_017923.4) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.241); catalogued as rs1391108124, COSV56811855; called by muse, mutect2, varscan2
- MDGA1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs1377890773, COSV51794003; called by muse, mutect2
- MRPS27 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV54649613, COSV54650471; called by muse, mutect2, varscan2
- MUC16 | c.26717C>T p.T8906I | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV67456477; called by muse, mutect2
- NDUFA10 | c.999G>C p.E333D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV53153509; called by muse, mutect2, varscan2
- NDUFV2 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.091); catalogued as COSV59187053; called by muse, mutect2, varscan2
- NUP205 | c.5360C>T p.S1787L | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV53657091; called by muse, mutect2
- OR13C4 | c.304T>C p.F102L | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV99470203; called by muse, mutect2
- OR2C3 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as COSV100825724; called by muse, mutect2
- OR7C1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 7/165 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV50183032; called by muse, mutect2
- PARD3 | c.1490G>T p.G497V | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60747495; called by muse, mutect2
- PCDHB12 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 12/89 reads (13%) | catalogued as rs142953283, COSV99507426; called by muse, mutect2, varscan2
- PCDHB16 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as COSV53360265; called by muse, mutect2
- PDE1A | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59519460, COSV59522807; called by muse, mutect2
- PLAC8L1 | c.352T>C p.F118L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV61013753; called by muse, mutect2, varscan2
- PLEKHG4B | c.3700G>A p.D1234N (on ENST00000283426; = p.D1590N on NM_052909.5) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs1429412876, COSV52045627, COSV52046339; called by muse, mutect2, varscan2
- POLQ | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV99952419; called by muse, mutect2
- PPFIA3 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs754601712, COSV61950708; called by muse, mutect2, varscan2
- PPIP5K2 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV58604483; called by muse, mutect2
- PPP4R4 | c.730G>T p.G244W | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100428746; called by muse, mutect2
- PRUNE2 | c.1931T>C p.M644T | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65039917; called by muse, mutect2
- PTPRD | c.3993G>C p.M1331I | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV61992450; called by muse, mutect2
- RBM7 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV57784196; called by muse, mutect2
- REG1A | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs760651470, COSV52069233; called by muse, mutect2, varscan2
- RIPOR3 | c.1425G>C p.E475D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV50387026; called by muse, mutect2, varscan2
- RPS6KA6 | c.1973A>G p.D658G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as COSV53118186; called by muse, mutect2, varscan2
- RSF1 | c.3495G>C p.K1165N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV57838278; called by muse, mutect2
- SATB2 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745320639, COSV53481317; called by muse, mutect2, varscan2
- SCRIB | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57584659; called by muse, mutect2, varscan2
- SCUBE2 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV58541707; called by muse, mutect2
- SLC6A14 | c.809T>G p.L270R | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV64146522; called by muse, mutect2
- SMC6 | c.1244A>G p.E415G | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV61173076; called by muse, mutect2
- SNAPC3 | c.953A>G p.E318G | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66402683; called by muse, mutect2, varscan2
- SNRPB | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100293358; called by muse, mutect2
- SORL1 | c.6455G>A p.G2152E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV52752028; called by muse, mutect2
- SPG11 | c.6646G>A p.E2216K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55990708; called by muse, mutect2
- TMPRSS9 | c.1888C>G p.L630V (on ENST00000648592; = p.L596V on NM_182973.2) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV60226671; called by muse, mutect2
- TMTC2 | c.684T>G p.I228M | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV58258339, COSV58264285; called by muse, mutect2
- TRMT5 | c.1361A>G p.N454S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as COSV54203214; called by muse, mutect2, varscan2
- TRPM3 | c.264-1G>A p.X88_splice (on ENST00000357533 / NM_001366142.2; = p.X57_splice on NM_001007471.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100623765, COSV62468890; called by muse, mutect2, varscan2
- TSHZ3 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV53667937; called by muse, mutect2, varscan2
- TTBK1 | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV52489749; called by muse, mutect2, varscan2
- TULP4 | c.385A>G p.S129G | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65574014; called by muse, mutect2
- TWF1 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57300267; called by muse, mutect2, varscan2
- ULK2 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV100860878; called by muse, varscan2
- UVRAG | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as COSV62102955; called by muse, mutect2
- WDFY3 | c.7312A>T p.K2438* | Nonsense Mutation (SNP) | VAF 7/100 reads (7%) | catalogued as COSV99884092; called by muse, mutect2
- WNK1 | c.6037G>C p.D2013H (on ENST00000315939 / NM_018979.4; = p.D1765H on NM_014823.3) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60029194, COSV60033010; called by muse, mutect2
- ZFYVE1 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV59612759; called by muse, mutect2
- ZNF143 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV55179142; called by muse, mutect2
- ZNF208 | c.1319T>G p.L440R | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68103146; called by muse, mutect2
- ZNF350 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as rs759224562, COSV54708230; called by muse, mutect2, varscan2
- ZNF491 | c.399T>G p.C133W | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60057061, COSV60058841; called by muse, mutect2
- ZNF721 | c.195G>C p.Q65H (on ENST00000338977; = p.Q77H on NM_133474.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as rs1246256575, COSV59090853; called by muse, mutect2, varscan2
- ZNF823 | c.587T>C p.L196S (on ENST00000341191 / NM_001297610.2; = p.L152S on NM_017507.2) | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.44); PolyPhen probably damaging (1); catalogued as COSV57873152; called by muse, mutect2
- ATG2B | c.39del p.C14Afs*17 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- ATP12A | c.1445_1446del p.V482Dfs*4 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | called by pindel, varscan2
- JMJD7-PLA2G4B | c.2149A>G p.M717V | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- OBSCN | c.6691dup p.D2231Gfs*8 | Frame Shift Ins (INS) | VAF 7/26 reads (27%) | called by mutect2, pindel, varscan2
- SHROOM2 | c.2422G>A p.V808I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- ZNF226 | c.1148_1149del p.R383Tfs*11 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by pindel, varscan2
- AGO3 | c.331T>C p.L111= | Silent (SNP) | VAF 4/75 reads (5%) | catalogued as COSV99868835; called by muse, mutect2
- APCS | c.195C>T p.A65= | Silent (SNP) | VAF 7/154 reads (5%) | catalogued as rs1450856660, COSV54817720; called by muse, mutect2
- BEST4 | c.567C>T p.T189= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as COSV64733718; called by muse, mutect2
- BTBD16 | c.1431C>T p.T477= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV53261883; called by muse, mutect2
- C3 | c.132G>T p.L44= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV55571008; called by muse, mutect2
- CAND1 | c.15G>C p.S5= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs762926113, COSV73338852, COSV73338933; called by muse, mutect2, varscan2
- CEP170B | c.2640G>A p.A880= (on ENST00000453495; = p.A809= on NM_015005.3) | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs369204907; called by muse, mutect2
- CHCHD7 | c.15A>G p.T5= (on ENST00000355315 / NM_001011671.3; = p.T17= on NM_024300.4) | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as COSV57610266; called by muse, mutect2
- EHD3 | c.75C>G p.L25= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV59029899; called by muse, mutect2, varscan2
- EVC2 | c.3846G>A p.E1282= | Silent (SNP) | VAF 14/205 reads (7%) | catalogued as COSV60390722, COSV60398334, COSV60399248; called by muse, mutect2
- FBXO42 | c.198G>A p.Q66= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV65045251, COSV65045811; called by muse, mutect2, varscan2
- GPR17 | c.951C>T p.N317= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs200424519; called by muse, mutect2, varscan2
- HELZ2 | c.2187C>T p.H729= (on ENST00000467148 / NM_001037335.2; = p.H160= on NM_033405.3) | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs780288859, COSV64409358; called by muse, mutect2, varscan2
- HEXD | c.555G>A p.V185= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as COSV60063422; called by muse, mutect2
- KDM3B | c.564A>G p.Q188= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV58689615, COSV58695069; called by muse, mutect2, varscan2
- KRTAP10-2 | c.123C>T p.P41= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV59956998; called by muse, mutect2
- LRRC46 | c.570G>A p.L190= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV51635333; called by muse, mutect2
- LY6G6F-LY6G6D | c.913C>T p.L305= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV65419457; called by muse, mutect2, varscan2
- MAGI2 | c.399C>T p.L133= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as rs1417284831, COSV62652751; called by muse, mutect2
- OR8S1 | c.129G>C p.L43= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as COSV59599659; called by muse, mutect2, varscan2
- PARP4 | c.3963G>A p.P1321= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs370744509; called by muse, mutect2, varscan2
- PCDHB16 | c.231C>T p.L77= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV53360263; called by muse, mutect2
- PCDHB8 | c.783G>C p.L261= | Silent (SNP) | VAF 13/204 reads (6%) | catalogued as COSV50759931; called by muse, mutect2
- RAB4B | c.324C>T p.T108= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as rs1349285239, COSV63824541; called by muse, mutect2
- RSF1 | c.1416T>C p.Y472= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs1213506696, COSV57838288; called by muse, mutect2
- SERPINI1 | c.684T>C p.F228= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs557897218, COSV55509595; ClinVar: likely benign; called by muse, mutect2, varscan2
- SI | c.5055C>T p.V1685= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as COSV52272167; called by muse, mutect2
- SLC26A3 | c.918C>A p.G306= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV60639616; called by muse, mutect2
- SLC29A1 | c.348G>A p.L116= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV57577786; called by muse, mutect2, varscan2
- SMARCC1 | c.1218G>T p.A406= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as COSV54379035, COSV54384858; called by muse, mutect2
- SP2 | c.75C>A p.S25= | Silent (SNP) | VAF 6/136 reads (4%) | catalogued as COSV65063728; called by muse, mutect2
- SPATA31D1 | c.2244C>T p.S748= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs191755245; called by muse, mutect2, varscan2
- SPTA1 | c.816T>C p.D272= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV63751150; called by muse, mutect2, varscan2
- STARD10 | c.390C>T p.V130= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100600462; called by muse, mutect2
- SYCP2L | c.2106T>A p.G702= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV51651711, COSV99305448; called by muse, mutect2
- THRB | c.180G>A p.Q60= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV62835597; called by muse, mutect2
- TMEM132D | c.2298G>A p.L766= | Silent (SNP) | VAF 7/155 reads (5%) | catalogued as rs1438612615, COSV67159664; called by muse, mutect2
- TOGARAM1 | c.297C>G p.L99= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV100753222, COSV61887775; called by muse, mutect2
- TRPV6 | c.735C>G p.L245= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV63891130; called by muse, mutect2, varscan2
- USP22 | c.231C>G p.L77= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV54946026; called by muse, mutect2
- VAPB | c.381A>T p.A127= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as COSV55666953; called by muse, mutect2, varscan2
- AL136982.4 | n.484G>A | RNA (SNP) | VAF 43/412 reads (10%) | catalogued as rs747823913; called by muse, mutect2, varscan2
- DCHS2 | n.3028A>T | RNA (SNP) | VAF 18/141 reads (13%) | catalogued as COSV59722413; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2481+5626G>A | Intron (SNP) | VAF 16/242 reads (7%) | catalogued as COSV52174866; called by muse, mutect2
- SSX5 | c.69+184C>G | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as COSV61254814; called by mutect2, varscan2
